Somatic mutation profile of tumor specimen TCGA-CV-6953-01A (aliquot TCGA-CV-6953-01A-11D-1912-08) from TCGA case TCGA-CV-6953, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage III; Tumor grade: G1; Age at diagnosis: 80.7 years (29,465 days).
Specimen TCGA-CV-6953-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4b26f380-d0d3-4359-9e9e-3d32fdf690da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-6953-10A (Blood Derived Normal), aliquot TCGA-CV-6953-10A-01D-1912-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ea31b145-61d3-4339-8dce-f570c680e5d6

The open-access MAF lists 114 somatic variants for this specimen: 90 protein-altering or splice-affecting, 24 silent.
By variant classification: Missense Mutation 80, Silent 24, Nonsense Mutation 7, Frame Shift Del 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 11/20 reads (55%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 19/70 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC9 | c.3605C>T p.T1202M | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.782); catalogued as CM140385, COSV53978242; called by muse, mutect2, varscan2
- ACRBP | c.1097G>A p.R366Q | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1324862088, COSV99975797; called by muse, mutect2, varscan2
- ARHGEF12 | c.217G>A p.V73I | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs34754222; called by muse, mutect2, varscan2
- ATP8B3 | c.1612G>A p.A538T | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as rs879197642, COSV100033765; called by muse, mutect2, varscan2
- C1orf109 | c.325G>A p.V109M | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV100787425; called by muse, mutect2, varscan2
- CASP8 | c.1303C>T p.R435* (on ENST00000432109 / NM_033355.3; = p.R452* on NM_001228.4) | Nonsense Mutation (SNP) | VAF 16/73 reads (22%) | catalogued as rs1368296717, COSV51844657; called by muse, mutect2, varscan2
- CDH12 | c.898C>A p.Q300K | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV101200629; called by muse, mutect2, varscan2
- CDK4 | c.647G>A p.G216E | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99225825, COSV99226116; called by muse, mutect2, varscan2
- CEP126 | c.1178G>T p.R393M | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); catalogued as COSV54832197, COSV99680386; called by muse, mutect2, varscan2
- CHSY1 | c.869G>C p.R290T | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.061); catalogued as COSV54255221; called by muse, mutect2, varscan2
- CLEC12B | c.442C>T p.Q148* | Nonsense Mutation (SNP) | VAF 23/120 reads (19%) | catalogued as COSV100138851; called by muse, mutect2, varscan2
- CTNNAL1 | c.752G>A p.C251Y | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100336224; called by muse, mutect2, varscan2
- CTTNBP2NL | c.1799C>T p.T600I | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.543); catalogued as COSV99599678; called by muse, mutect2, varscan2
- CYP4F12 | c.1178C>T p.P393L | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100215525; called by muse, mutect2, varscan2
- DENND4C | c.3977C>G p.S1326* (on ENST00000434457 / NM_001330640.2; = p.S1277* on NM_017925.7) | Nonsense Mutation (SNP) | VAF 12/110 reads (11%) | catalogued as COSV100727269, COSV63008980; called by muse, mutect2, varscan2
- DENND5B | c.2963G>A p.G988E | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100170659; called by muse, mutect2, varscan2
- DYNC1H1 | c.3643G>A p.E1215K | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as COSV100794145, COSV64139081; called by muse, mutect2, varscan2
- EPHA3 | c.1594T>A p.S532T | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.62); PolyPhen benign (0.014); catalogued as COSV100341605; called by muse, mutect2, varscan2
- ESPL1 | c.2137G>A p.E713K | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); catalogued as COSV99228647; called by muse, mutect2
- FAM47A | c.1393G>A p.E465K | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.296); catalogued as COSV100649640; called by muse, mutect2, varscan2
- FBXO34 | c.1636G>C p.E546Q | Missense Mutation (SNP) | VAF 43/168 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as rs965469131, COSV100571790; called by muse, mutect2, varscan2
- FBXO38 | c.3076C>G p.H1026D (on ENST00000340253 / NM_205836.3; = p.H951D on NM_030793.5) | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as COSV99692988; called by muse, mutect2, varscan2
- FBXO8 | c.891A>T p.Q297H | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV101183601; called by muse, mutect2, varscan2
- FLNB | c.4654C>G p.L1552V | Missense Mutation (SNP) | VAF 46/190 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV99911214; called by muse, varscan2
- GARRE1 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.987); catalogued as COSV100208860; called by muse, mutect2, varscan2
- GLIS1 | c.406C>T p.L136F | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs372634987; called by muse, mutect2, varscan2
- GNB1 | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs11554059, COSV66102387; called by muse, mutect2, varscan2
- GPR45 | c.190G>T p.A64S | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.688); catalogued as COSV51525046, COSV99306565; called by muse, mutect2, varscan2
- GTF2I | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 46/188 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100259343; called by muse, mutect2, varscan2
- HECW2 | c.1897G>A p.E633K | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.175); catalogued as COSV99038568, COSV99645295; called by muse, mutect2, varscan2
- HNRNPL | c.739G>C p.A247P | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99669832; called by muse, mutect2, varscan2
- IARS1 | c.614C>T p.S205L | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV100986751; called by muse, mutect2
- IRF2 | c.260C>T p.S87F | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101165727; called by muse, mutect2
- IRS4 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.113); catalogued as COSV100929385; called by muse, mutect2, varscan2
- ITGB1 | c.1113C>G p.I371M | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100171126; called by muse, mutect2
- KIF24 | c.1105G>A p.D369N | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100799062, COSV61455435, COSV61457655; called by muse, varscan2
- KRT35 | c.635T>G p.L212R | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV99877604; called by muse, mutect2, varscan2
- LAMC1 | c.1483T>A p.C495S | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99278651; called by muse, mutect2, varscan2
- MBOAT1 | c.907+1G>A p.X303_splice | Splice Site (SNP) | VAF 12/62 reads (19%) | catalogued as rs952347486, COSV100208244; called by muse, mutect2, varscan2
- MEA1 | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 39/226 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.197); catalogued as rs754577473, COSV99775513; called by muse, mutect2, varscan2
- MEI1 | c.3421G>C p.D1141H | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); catalogued as COSV100299385; called by muse, mutect2, varscan2
- MUC3A | c.7640C>A p.T2547N | Missense Mutation (SNP) | VAF 56/356 reads (16%) | SIFT deleterious, low confidence (0); catalogued as rs374517359; called by muse, mutect2, varscan2
- MYH7 | c.4315G>A p.A1439T | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as CM135492, COSV100805537; called by muse, mutect2, varscan2
- NEIL2 | c.421G>A p.V141I | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs113905789; called by muse, varscan2
- NOD2 | c.1780G>A p.G594R | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.799); catalogued as COSV100318054; called by muse, mutect2, varscan2
- NRK | c.3868G>A p.E1290K | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV99686205; called by muse, mutect2, varscan2
- OLFM1 | c.1331A>G p.N444S (on ENST00000371793 / NM_001282611.2; = p.N426S on NM_014279.5) | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99422908; called by muse, mutect2, varscan2
- OR1E2 | c.572C>A p.S191Y | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.081); catalogued as COSV99943337; called by muse, mutect2, varscan2
- OR4D6 | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 48/176 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.589); catalogued as COSV100271513; called by muse, mutect2, varscan2
- OR51I2 | c.823C>A p.L275I | Missense Mutation (SNP) | VAF 49/216 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.371); catalogued as COSV100413453, COSV58300522; called by muse, mutect2, varscan2
- OSGEPL1 | c.526_529del p.L176Wfs*3 | Frame Shift Del (DEL) | VAF 16/95 reads (17%) | catalogued as rs749111152; called by pindel, varscan2
- PAX4 | c.586G>A p.D196N | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100489890; called by muse, mutect2, varscan2
- PDE1B | c.1176C>G p.F392L | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV54492049; called by muse, mutect2, varscan2
- PER1 | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 44/154 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs771354956, COSV100424141; called by muse, mutect2, varscan2
- PHYHIPL | c.880G>T p.E294* | Nonsense Mutation (SNP) | VAF 22/80 reads (28%) | catalogued as COSV99512824; called by muse, mutect2, varscan2
- PLEKHH2 | c.2603A>T p.D868V | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as COSV99174238; called by muse, mutect2, varscan2
- PLK2 | c.1678G>A p.D560N | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.139); catalogued as COSV99955672; called by muse, mutect2, varscan2
- PRKACA | c.248T>C p.L83P | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs1440498804, COSV58069907; called by muse, mutect2, varscan2
- PSD3 | c.1454G>A p.R485H | Missense Mutation (SNP) | VAF 48/212 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.213); catalogued as rs573668110, COSV100496176, COSV58967240; called by muse, varscan2
- QRICH2 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as rs138229886; called by muse, mutect2, varscan2
- RBL2 | c.3347G>C p.R1116T | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100043156; called by muse, mutect2, varscan2
- RS1 | c.482T>G p.L161R | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.839); catalogued as COSV101183674; called by muse, mutect2
- SECISBP2L | c.2437G>A p.E813K (on ENST00000559471 / NM_001193489.2; = p.E768K on NM_014701.4) | Missense Mutation (SNP) | VAF 59/275 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.525); catalogued as COSV99959640; called by muse, mutect2, varscan2
- SHC4 | c.1501C>T p.Q501* | Nonsense Mutation (SNP) | VAF 5/18 reads (28%) | catalogued as COSV100194021; called by muse, mutect2
- SLC1A2 | c.1225G>A p.A409T | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); catalogued as rs1022532582, COSV99553667; called by muse, mutect2, varscan2
- SLC29A3 | c.689C>T p.A230V | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV100928384; called by muse, mutect2, varscan2
- SLC38A8 | c.577G>A p.V193M | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); catalogued as rs930213649, COSV55304722; called by muse, mutect2, varscan2
- SLC4A11 | c.2662G>A p.E888K | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.437); catalogued as COSV101195858; called by muse, mutect2, varscan2
- SLC4A2 | c.2795G>A p.R932Q | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99879432; called by muse, mutect2, varscan2
- SLC7A9 | c.994G>A p.G332S | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.206); catalogued as COSV99195164; called by muse, mutect2, varscan2
- SYT1 | c.423G>T p.E141D | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.147); catalogued as COSV99693042; called by muse, mutect2, varscan2
- TAS2R16 | c.618G>T p.Q206H | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.723); catalogued as COSV99972099; called by muse, mutect2, varscan2
- TEKT3 | c.257A>G p.N86S | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs774458615, COSV100106671; called by muse, mutect2, varscan2
- THAP4 | c.241G>A p.V81M | Missense Mutation (SNP) | VAF 41/175 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV101125978, COSV67190855; called by muse, mutect2, varscan2
- TMEM187 | c.239T>C p.L80P | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100890120; called by muse, mutect2, varscan2
- TTC37 | c.3581C>A p.A1194D | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.255); catalogued as COSV100706235; called by muse, mutect2, varscan2
- UGT2B10 | c.665G>C p.W222S | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.493); catalogued as rs779971456, COSV99607708; called by muse, mutect2, varscan2
- USF3 | c.2752C>T p.Q918* | Nonsense Mutation (SNP) | VAF 36/136 reads (26%) | catalogued as COSV100324566; called by muse, mutect2, varscan2
- USP29 | c.2362G>T p.G788C | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.463); catalogued as rs148519716, COSV99517458; called by muse, mutect2, varscan2
- WNT3 | c.953G>A p.G318D | Missense Mutation (SNP) | VAF 35/170 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56644832, COSV56646464; called by muse, mutect2, varscan2
- WRNIP1 | c.1297G>A p.A433T | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as COSV101062652; called by muse, mutect2, varscan2
- ZDBF2 | c.218C>A p.T73N | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.497); catalogued as COSV100984244; called by muse, mutect2, varscan2
- ZNF174 | c.367G>T p.D123Y | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as COSV99237093; called by muse, mutect2, varscan2
- ZNF33B | c.378T>A p.F126L | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100847549; called by muse, mutect2, varscan2
- ZNF804B | c.1370G>C p.W457S | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100301126, COSV60825714; called by muse, mutect2, varscan2
- CRYBG2 | c.386G>T p.R129M | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGHG3 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 41/170 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ZAN | c.3827_3828del p.Y1276Cfs*19 | Frame Shift Del (DEL) | VAF 6/46 reads (13%) | called by mutect2, varscan2
- ABCA3 | c.2040C>T p.I680= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as rs776349377, COSV100067824; called by muse, mutect2, varscan2
- AGK | c.654C>T p.G218= | Silent (SNP) | VAF 26/93 reads (28%) | catalogued as rs144977618, COSV100814493; called by muse, mutect2, varscan2
- ALLC | c.96G>A p.P32= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as rs561864863, COSV99377303; called by muse, mutect2, varscan2
- AQP10 | c.243G>A p.L81= | Silent (SNP) | VAF 25/102 reads (25%) | catalogued as COSV100269840; called by muse, mutect2, varscan2
- ATP7B | c.1692C>T p.G564= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV99665905; called by muse, mutect2, varscan2
- B3GAT1 | c.405C>T p.R135= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV56995903; called by muse, mutect2, varscan2
- CACNG2 | c.84G>T p.V28= | Silent (SNP) | VAF 51/213 reads (24%) | catalogued as COSV100268345; called by muse, mutect2, varscan2
- CPSF2 | c.445C>T p.L149= | Silent (SNP) | VAF 15/84 reads (18%) | catalogued as rs768832098, COSV54099201; called by muse, mutect2, varscan2
- DACH1 | c.1917A>G p.Q639= (on ENST00000619232 / NM_001366712.1; = p.Q385= on NM_004392.6) | Silent (SNP) | VAF 21/119 reads (18%) | catalogued as COSV100497237; called by muse, mutect2, varscan2
- FSTL4 | c.1377C>T p.D459= | Silent (SNP) | VAF 21/110 reads (19%) | catalogued as rs767927742, COSV54786391; called by muse, mutect2, varscan2
- GRIK3 | c.2301C>T p.I767= | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as rs766887566, COSV100901008; called by muse, mutect2, varscan2
- KAT6A | c.4107C>T p.T1369= | Silent (SNP) | VAF 16/112 reads (14%) | catalogued as rs371651920; called by muse, mutect2, varscan2
- KCTD20 | c.789G>C p.L263= | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as COSV99535675; called by muse, mutect2, varscan2
- KRT37 | c.294C>T p.N98= | Silent (SNP) | VAF 19/90 reads (21%) | catalogued as COSV99845163; called by muse, mutect2, varscan2
- MED12 | c.1245G>A p.Q415= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as COSV100375199; called by muse, mutect2, varscan2
- MYH9 | c.4233G>T p.L1411= | Silent (SNP) | VAF 10/90 reads (11%) | catalogued as COSV99337543; called by muse, varscan2
- OBSL1 | c.4767G>A p.S1589= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as rs759999748, COSV99522535; called by muse, mutect2, varscan2
- PCDHGB5 | c.1593C>T p.R531= | Silent (SNP) | VAF 7/35 reads (20%) | called by muse, mutect2, varscan2
- PRKD1 | c.408C>T p.S136= | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as rs747688196, COSV100118926; called by muse, mutect2, varscan2
- PRR12 | c.1236G>A p.K412= (on ENST00000615927; = p.K1233= on NM_020719.3) | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV101330525; called by muse, mutect2, varscan2
- RGS21 | c.414T>C p.N138= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as COSV101313964; called by muse, mutect2, varscan2
- RPS6KC1 | c.1512A>C p.S504= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as rs752381553, COSV100873725; called by muse, mutect2, varscan2
- SLC35F1 | c.54G>A p.P18= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as COSV100837318; called by muse, mutect2, varscan2
- ZKSCAN8 | c.870C>T p.N290= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as rs759829097, COSV57640121; called by muse, mutect2, varscan2
